Somatic mutation profile of tumor specimen TCGA-DD-AADS-01A (aliquot TCGA-DD-AADS-01A-11D-A40R-10) from TCGA case TCGA-DD-AADS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.6 years (23,227 days).
Specimen TCGA-DD-AADS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a57634-7af5-4c7b-8ad7-489a22c8fbfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADS-10A (Blood Derived Normal), aliquot TCGA-DD-AADS-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2014f28d-9945-4fd1-860c-cd4af5a749c7

The open-access MAF lists 161 somatic variants for this specimen: 123 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 35, Splice Site 7, Nonsense Mutation 7, Frame Shift Del 5, Intron 2, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735836; called by muse, mutect2, varscan2
- ABCA12 | c.6088T>A p.Y2030N (on ENST00000272895 / NM_173076.3; = p.Y1712N on NM_015657.3) | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99791987; called by muse, mutect2, varscan2
- ACIN1 | c.1988A>G p.D663G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs920497782, COSV99400314; called by muse, mutect2, varscan2
- ANGPTL7 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs554783669, COSV100816653; called by muse, mutect2, varscan2
- ANKRD12 | c.1951A>G p.K651E | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV100042087; called by muse, mutect2, varscan2
- ASH1L | c.7382A>G p.D2461G (on ENST00000368346 / NM_001366177.2; = p.D2456G on NM_018489.3) | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100853598; called by muse, mutect2, varscan2
- ATG4A | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100619871; called by muse, mutect2, varscan2
- AXIN1 | c.1819A>T p.K607* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99250308; called by muse, mutect2, varscan2
- BBOX1 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as COSV99590001; called by muse, mutect2, varscan2
- BRD4 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV99651401; called by muse, mutect2, varscan2
- BZW2 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as COSV99334878; called by muse, mutect2, varscan2
- CD5L | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs749053734, COSV63820970, COSV63822649; called by muse, mutect2, varscan2
- CFAP54 | c.5038T>G p.Y1680D | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100733331; called by muse, mutect2, varscan2
- COL28A1 | c.2797G>C p.G933R | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258936, COSV68085130; called by muse, mutect2, varscan2
- COLEC12 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101232170; called by muse, mutect2, varscan2
- COX4I2 | c.247T>A p.L83M | Missense Mutation (SNP) | VAF 325/1602 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101064278; called by muse, mutect2, varscan2
- CXCL6 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs999888344, COSV99885020; called by muse, mutect2, varscan2
- CYP4A11 | c.890T>C p.L297S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV100152637; called by muse, mutect2, varscan2
- CYP4B1 | c.773-2A>G p.X258_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99597487; called by muse, mutect2, varscan2
- DENND1A | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101010790; called by muse, mutect2, varscan2
- DGKD | c.271A>G p.I91V (on ENST00000264057 / NM_152879.3; = p.I47V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.098); catalogued as rs763217681, COSV99897597; called by muse, mutect2, varscan2
- DPYSL3 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as COSV100575384, COSV58327214; called by mutect2, varscan2
- EDA | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99339784; called by muse, mutect2, varscan2
- ESM1 | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101195722, COSV67318458; called by muse, mutect2, varscan2
- FABP2 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99917005; called by muse, mutect2
- FUOM | c.325A>G p.R109G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99529504; called by muse, mutect2, varscan2
- FZD8 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV101020267; called by muse, mutect2, varscan2
- GABRG1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778743; called by muse, mutect2, varscan2
- GABRG2 | c.1482C>G p.C494W (on ENST00000361925 / NM_001375343.1; = p.C454W on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100729853; called by muse, mutect2, varscan2
- GANAB | c.539A>G p.H180R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1417175965, COSV60468117; called by muse, mutect2, varscan2
- GATD1 | c.656+1G>T p.X219_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100168777; called by muse, mutect2, varscan2
- GJB6 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.158); catalogued as COSV99576156; called by muse, mutect2, varscan2
- GPRIN2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); catalogued as rs988211125, COSV65401333; called by muse, mutect2
- GTF3C5 | c.982A>C p.K328Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV100565560; called by muse, mutect2, varscan2
- GYS2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53927627; called by muse, mutect2
- HAUS1 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99959586; called by muse, mutect2, varscan2
- HMSD | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV101282950; called by muse, mutect2, varscan2
- HOXC11 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99678533; called by muse, mutect2, varscan2
- INO80 | c.3098A>T p.Y1033F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV100732072; called by muse, mutect2, varscan2
- INPP4B | c.256-2A>T p.X86_splice | Splice Site (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99526750; called by muse, mutect2, varscan2
- IQSEC2 | c.2831A>T p.N944I (on ENST00000642864 / NM_001111125.3; = p.N739I on NM_015075.2) | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100945096; called by muse, mutect2, varscan2
- IRF4 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101110951; called by muse, mutect2, varscan2
- ITGA1 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1364612253, COSV99252143; called by muse, mutect2, varscan2
- ITIH5 | c.1081T>A p.Y361N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV53666673; called by muse, mutect2, varscan2
- KLK7 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100304501; called by muse, mutect2, varscan2
- KLRC2 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101122748; called by muse, mutect2, varscan2
- KNDC1 | c.2063T>A p.V688E | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100466203; called by muse, mutect2, varscan2
- KRT15 | c.1248-2A>T p.X416_splice | Splice Site (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99563284; called by muse, mutect2, varscan2
- KRT32 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV99863181; called by muse, mutect2, varscan2
- L1TD1 | c.1732A>T p.S578C | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100776629; called by muse, mutect2, varscan2
- LRP8 | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100036907; called by muse, mutect2, varscan2
- MAP3K11 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201727045, COSV58418152; called by muse, mutect2, varscan2
- MITF | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100726892; called by muse, mutect2, varscan2
- MOCOS | c.2410-2A>T p.X804_splice | Splice Site (SNP) | VAF 4/90 reads (4%) | catalogued as COSV99733916; called by muse, mutect2
- MUC16 | c.36076C>A p.H12026N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV67447055; called by muse, mutect2, varscan2
- MYBPC3 | c.2053A>T p.K685* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99920960; called by muse, mutect2, varscan2
- MYH1 | c.3208A>T p.T1070S | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99876866; called by muse, mutect2, varscan2
- MYH13 | c.4196A>T p.Q1399L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV99355430; called by muse, mutect2, varscan2
- MYH14 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99221962; called by muse, mutect2, varscan2
- MYO1C | c.661C>G p.L221V (on ENST00000648651 / NM_001080779.2; = p.L186V on NM_033375.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100704551; called by muse, mutect2, varscan2
- NEFM | c.1651G>C p.G551R | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99647571; called by muse, mutect2, varscan2
- NF2 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100098701; called by muse, mutect2, varscan2
- NF2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 40/70 reads (57%) | catalogued as COSV100099424; called by muse, mutect2, varscan2
- NKD2 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV99724398; called by muse, mutect2, varscan2
- NKX2-4 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100698632; called by muse, mutect2, varscan2
- NLRP12 | c.418A>T p.M140L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100145898; called by muse, mutect2, varscan2
- NUP37 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV51838228; called by muse, mutect2, varscan2
- NXPH1 | c.682T>A p.S228T | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.585); catalogued as COSV101339799; called by muse, mutect2
- OR14C36 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100507650; called by muse, mutect2, varscan2
- OR2G2 | c.361A>T p.M121L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100189990; called by muse, mutect2, varscan2
- PCDHB16 | c.1884G>T p.R628S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99502861; called by muse, mutect2, varscan2
- PCNX2 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1185651086, COSV99269464; called by muse, mutect2, varscan2
- PDE1C | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100373788; called by muse, mutect2, varscan2
- PGBD5 | c.294G>C p.M98I (on ENST00000525115; = p.M167I on NM_001258311.2) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100358874; called by muse, mutect2, varscan2
- PHF1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV100992688; called by muse, mutect2, varscan2
- PHIP | c.3070G>C p.A1024P | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99244888; called by muse, mutect2, varscan2
- PLEC | c.4018G>A p.E1340K (on ENST00000322810 / NM_201380.4; = p.E1230K on NM_000445.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1416611970, COSV100518859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLIPRP2 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100077988; called by muse, mutect2
- PTCHD4 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.361); catalogued as COSV100261639, COSV59795543; called by muse, mutect2, varscan2
- PTGR2 | c.418T>A p.S140T | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV99966461; called by muse, mutect2, varscan2
- PWWP2B | c.1294A>G p.R432G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100535933, COSV59450626; called by muse, mutect2, varscan2
- RAB26 | c.652T>C p.F218L | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1216911050, COSV99270007; called by muse, mutect2, varscan2
- RBBP8 | c.823A>C p.M275L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100507657; called by muse, mutect2, varscan2
- RTP2 | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100833018; called by muse, mutect2, varscan2
- RYR2 | c.7814T>A p.M2605K | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100772861; called by muse, mutect2, varscan2
- SCN2A | c.3008T>C p.L1003P | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333477; called by muse, mutect2, varscan2
- SDK2 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs779304466, COSV101168579; called by muse, mutect2, varscan2
- SEMA6D | c.659A>T p.E220V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100317609; called by muse, mutect2, varscan2
- SETMAR | c.413A>C p.Q138P | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV100740903; called by muse, mutect2, varscan2
- SGCE | c.340+2T>C p.X114_splice (on ENST00000647096; = p.X78_splice on NM_003919.3) | Splice Site (SNP) | VAF 221/454 reads (49%) | catalogued as CS062103, COSV99722916; called by muse, mutect2, varscan2
- SLC19A2 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.557); catalogued as COSV99357139; called by muse, mutect2, varscan2
- SLC37A3 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.216); catalogued as COSV100405704, COSV58265182; called by muse, mutect2, varscan2
- SLC52A3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 129/203 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99448386; called by muse, mutect2, varscan2
- SLC5A7 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50889056, COSV99887234; called by muse, mutect2, varscan2
- SLCO3A1 | c.842T>A p.L281* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100575911; called by muse, mutect2, varscan2
- SMARCB1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV99575745; called by muse, mutect2, varscan2
- SPATA20 | c.919G>A p.G307R (on ENST00000356488 / NM_001258372.1; = p.G323R on NM_022827.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136686; called by muse, mutect2, varscan2
- SPTA1 | c.5894C>A p.T1965N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV100935565; called by muse, mutect2, varscan2
- SPTBN1 | c.4570A>G p.I1524V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.155); catalogued as rs1429177630, COSV100443395; called by muse, mutect2, varscan2
- STMN1 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.25); catalogued as COSV100771365; called by muse, mutect2, varscan2
- SYCP2 | c.1736G>C p.S579T | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100698443; called by muse, mutect2
- THSD7B | c.4236G>T p.E1412D (on ENST00000272643; = p.E1410D on NM_001316349.2) | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV55685227, COSV99758030; called by muse, mutect2, varscan2
- TMEFF2 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as rs200174014, COSV55829678; called by muse, mutect2, varscan2
- TMPRSS15 | c.2451T>A p.S817R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV99519288; called by muse, mutect2, varscan2
- TRIP12 | c.5384C>G p.T1795S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99390927; called by muse, mutect2, varscan2
- TTLL5 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as rs1049723430, COSV99709787; called by muse, mutect2
- UBE3C | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100780089; called by muse, mutect2, varscan2
- USP7 | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100784418; called by muse, mutect2, varscan2
- VPS39 | c.1665C>G p.F555L (on ENST00000348544 / NM_001301138.2; = p.F544L on NM_015289.5) | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.217); catalogued as COSV100529583, COSV58788574, COSV58789761; called by muse, mutect2, varscan2
- WNT7B | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV100255292; called by muse, varscan2
- WNT9A | c.934A>T p.R312W | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99688459; called by muse, mutect2, varscan2
- XIRP2 | c.7958T>C p.I2653T (on ENST00000628543; = p.I2828T on NM_152381.6) | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99747357; called by mutect2, varscan2
- ZNF506 | c.1330A>G p.R444G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101475664; called by muse, mutect2, varscan2
- ZNF714 | c.1202A>T p.E401V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs760638774, COSV99395573; called by muse, mutect2, varscan2
- A2ML1 | c.1683+1del | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | called by mutect2, pindel, varscan2
- ARL13B | c.655del p.R219Efs*42 (on ENST00000394222 / NM_001174150.2; = p.R112Efs*42 on NM_144996.4) | Frame Shift Del (DEL) | VAF 147/504 reads (29%) | called by mutect2, pindel, varscan2
- CEMIP | c.2857del p.D953Ifs*64 | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- DHX35 | c.124dup p.Y42Lfs*19 | Frame Shift Ins (INS) | VAF 21/151 reads (14%) | called by mutect2, pindel, varscan2
- FAM120A | c.1199C>G p.P400R | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); called by muse, varscan2
- FRYL | c.6095del p.H2032Lfs*20 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | called by mutect2, pindel*, varscan2
- ICE1 | c.2927_2928dup p.V977Qfs*33 | Frame Shift Ins (INS) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- SLC6A13 | c.338-16_338-1del p.X113_splice | Splice Site (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- ZBTB44 | c.182_216del p.V61Gfs*25 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | called by mutect2, pindel
- AKAP3 | c.2244C>A p.P748= | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as COSV99961743, COSV99961835; called by muse, varscan2
- B3GAT2 | c.624T>A p.P208= | Silent (SNP) | VAF 69/225 reads (31%) | catalogued as COSV100017423; called by muse, mutect2, varscan2
- CASR | c.276G>T p.T92= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV99949475, COSV99949478; called by muse, mutect2, varscan2
- CDH23 | c.7443T>A p.P2481= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV99823773; called by muse, mutect2, varscan2
- COLEC12 | c.1491C>T p.G497= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs757681445, COSV68372306; called by muse, mutect2, varscan2
- DCAF6 | c.1053A>G p.R351= | Silent (SNP) | VAF 109/282 reads (39%) | catalogued as COSV100394846; called by muse, mutect2, varscan2
- EFNB2 | c.159G>A p.Q53= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV99808945; called by muse, mutect2, varscan2
- ENPP6 | c.46C>T p.L16= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV99699140; called by muse, mutect2, varscan2
- ENTPD7 | c.285C>G p.S95= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as rs774747547, COSV100978490; called by muse, mutect2, varscan2
- FCRL6 | c.18T>A p.A6= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100220411; called by muse, mutect2, varscan2
- FLG2 | c.6975A>T p.A2325= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV101166222; called by muse, mutect2, varscan2
- FMN2 | c.2706G>T p.L902= | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as COSV100141978, COSV100147087; called by muse, mutect2, varscan2
- LMTK2 | c.348A>T p.P116= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV99807707; called by muse, mutect2, varscan2
- MAP2 | c.3756A>T p.S1252= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV99561663; called by muse, mutect2, varscan2
- MYO18A | c.1497T>C p.S499= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100572727; called by muse, mutect2, varscan2
- PAICS | c.1212A>T p.A404= | Silent (SNP) | VAF 73/220 reads (33%) | catalogued as COSV99947888; called by muse, mutect2, varscan2
- PCDH12 | c.2832C>T p.A944= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs375930414, COSV99191363; called by muse, mutect2, varscan2
- PCDHA12 | c.423T>A p.P141= | Silent (SNP) | VAF 70/207 reads (34%) | catalogued as COSV100254366; called by muse, mutect2, varscan2
- PCDHA13 | c.924A>T p.L308= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV99169714; called by muse, mutect2, varscan2
- PCDHAC2 | c.2346A>G p.R782= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs781784282, COSV99162182; called by muse, mutect2, varscan2
- PDLIM4 | c.570G>T p.V190= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99517028; called by muse, mutect2, varscan2
- RFK | c.390A>T p.L130= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100946914; called by muse, mutect2, varscan2
- RPAP1 | c.3492G>A p.L1164= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100427341; called by muse, mutect2, varscan2
- SEMA3A | c.1515A>G p.S505= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as rs1380666988, COSV99547681, COSV99547934; called by muse, mutect2
- SERPINE3 | c.1260T>C p.N420= | Silent (SNP) | VAF 9/194 reads (5%) | catalogued as rs1337650229, COSV100247263; called by muse, mutect2
- SLC2A3 | c.252C>T p.F84= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as rs749874527, COSV50002725; called by muse, mutect2, varscan2
- ST18 | c.2118A>T p.P706= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99391024; called by muse, mutect2, varscan2
- STAU2 | c.1500G>T p.L500= (on ENST00000524300 / NM_001164380.2; = p.L468= on NM_014393.2) | Silent (SNP) | VAF 20/235 reads (9%) | catalogued as COSV100869282; called by muse, mutect2
- TERT | c.2604T>C p.D868= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV99720734; called by muse, mutect2, varscan2
- TLK1 | c.1593A>T p.T531= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV100688821; called by muse, mutect2, varscan2
- TOP1 | c.462A>G p.T154= | Silent (SNP) | VAF 81/476 reads (17%) | catalogued as COSV100793961; called by muse, mutect2, varscan2
- TRDMT1 | c.1152A>G p.K384= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100666343; called by muse, mutect2, varscan2
- TTC7B | c.2148A>T p.T716= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV100128593; called by muse, mutect2, varscan2
- UGT2B7 | c.555A>G p.G185= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV100535326; called by muse, mutect2, varscan2
- WDR64 | c.1602G>A p.E534= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as COSV100844053; called by muse, mutect2, varscan2
- ASIC2 | c.556-179732A>G | Intron (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99861113; called by muse, mutect2, varscan2
- OBSCN | c.4585+2668A>T | Intron (SNP) | VAF 31/94 reads (33%) | catalogued as COSV99471389, COSV99484153; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120969 C>T | 3'Flank (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
